Somatic mutation profile of tumor specimen BA3168D (aliquot aq-BA3168D) from BEATAML1.0 case 2661, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.5 years (23,178 days).
Specimen BA3168D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd99f14b-319c-4d00-9b4b-db9fbfae0c95.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3443D (Solid Tissue Normal), aliquot aq-BA3443D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd54a492-6f9c-4532-8739-6d2d355b94e7

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.464C>A p.T155N | Missense Mutation (SNP) | VAF 57/72 reads (79%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as rs786202752, CM942117, HM090066, COSV52692291, COSV52711720, COSV52741190, COSV52782333; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CDHR2 | c.3206+1G>A p.X1069_splice | Splice Site (SNP) | VAF 30/75 reads (40%) | catalogued as rs200931823, COSV99991210; called by muse, mutect2, varscan2
- PCDHAC1 | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 97/119 reads (82%) | SIFT tolerated (0.05); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- SEL1L2 | c.126C>A p.N42K | Missense Mutation (SNP) | VAF 44/208 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by mutect2, varscan2
- RAB11FIP1 | c.3798C>A p.T1266= (on ENST00000330843 / NM_001002814.3; = p.T632= on NM_025151.5) | Silent (SNP) | VAF 54/199 reads (27%) | called by muse, mutect2, varscan2
- SNED1 | c.1125C>T p.C375= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as rs1173949099, COSV60023639; called by muse, mutect2
